Somatic mutation profile of tumor specimen C3L-02544-01 (aliquot CPT0113120009) from CPTAC case C3L-02544, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 57.7 years (21,058 days).
Specimen C3L-02544-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ab51ad1-19e5-4869-8216-4542a6e6dac8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02544-31 (Blood Derived Normal), aliquot CPT0115240002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/830a32d9-9e1c-482c-9805-14cafa5f9fc2

The open-access MAF lists 63 somatic variants for this specimen: 42 protein-altering or splice-affecting, 7 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Intron 7, Silent 7, Frame Shift Del 5, 3'UTR 3, Nonsense Mutation 2, 5'Flank 2, 5'UTR 2, In Frame Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD1 | c.2234C>T p.T745I | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV54387873; called by muse, mutect2, varscan2
- BMP5 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 84/524 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs371743666, COSV100895985, COSV63707374; called by muse, mutect2, varscan2
- LPIN2 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs1013107286; called by muse, mutect2, varscan2
- NUTM2E | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 64/361 reads (18%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs773745090; called by muse, mutect2, varscan2
- ULK3 | c.94T>C p.Y32H | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs1415479558; called by muse, mutect2, varscan2
- VHL | c.294C>A p.Y98* | Nonsense Mutation (SNP) | VAF 117/472 reads (25%) | catalogued as COSV56542810, COSV56543017; called by muse, mutect2, varscan2
- ZNF556 | c.594del p.S198Rfs*25 | Frame Shift Del (DEL) | VAF 54/286 reads (19%) | catalogued as COSV100298824; called by mutect2, pindel, varscan2
- AASS | c.2122T>G p.Y708D | Missense Mutation (SNP) | VAF 76/473 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC88A | c.2283A>T p.L761F | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CCDC88A | c.2282T>G p.L761* | Nonsense Mutation (SNP) | VAF 22/97 reads (23%) | called by muse, mutect2
- CCNDBP1 | c.524del p.L175* | Frame Shift Del (DEL) | VAF 31/183 reads (17%) | called by mutect2, pindel, varscan2
- CNTNAP2 | c.3275G>T p.G1092V | Missense Mutation (SNP) | VAF 99/564 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- COL11A1 | c.804dup p.Y269Ifs*2 | Frame Shift Ins (INS) | VAF 47/285 reads (16%) | called by mutect2, pindel, varscan2
- CSHL1 | c.657_659del p.C220del (on ENST00000309894 / NM_022581.3; = p.C126del on NM_001318.4) | In Frame Del (DEL) | VAF 81/378 reads (21%) | called by mutect2, pindel, varscan2
- CSTF2 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 50/244 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- DPP6 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 113/343 reads (33%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- DZIP3 | c.541G>C p.V181L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- EIF4G3 | c.4139A>T p.D1380V | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- EPS8 | c.590A>G p.D197G | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GAA | c.2823_2826delinsAAA p.L942Kfs*81 | Frame Shift Del (DEL) | VAF 65/510 reads (13%) | called by pindel, varscan2*
- GSK3A | c.833C>A p.S278Y | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF20B | c.3173A>G p.E1058G (on ENST00000371728 / NM_001284259.2; = p.E1018G on NM_016195.4) | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- LAMA4 | c.1926A>T p.E642D (on ENST00000230538 / NM_001105206.3; = p.E635D on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/234 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MAP4K4 | c.2102G>T p.G701V (on ENST00000347699 / NM_001242559.2; = p.G616V on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT tolerated, low confidence (0.52); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCOR1 | c.6722T>C p.V2241A | Missense Mutation (SNP) | VAF 41/187 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- OR2B11 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PBRM1 | c.1711del p.I571Lfs*16 | Frame Shift Del (DEL) | VAF 22/108 reads (20%) | called by mutect2, pindel, varscan2
- PRR12 | c.484G>T p.G162C (on ENST00000615927; = p.G983C on NM_020719.3) | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); called by muse, mutect2
- SETD2 | c.5824_5828del p.T1942Hfs*4 | Frame Shift Del (DEL) | VAF 65/276 reads (24%) | called by mutect2, pindel, varscan2
- SLC1A5 | c.742_744del p.L248del | In Frame Del (DEL) | VAF 30/293 reads (10%) | called by pindel, varscan2
- SLC39A12 | c.628G>C p.A210P | Missense Mutation (SNP) | VAF 80/397 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- SLC6A13 | c.1216T>A p.Y406N | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- SSNA1 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 110/377 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TAS2R20 | c.124T>A p.S42T | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- TCTN2 | c.145A>T p.T49S | Missense Mutation (SNP) | VAF 97/410 reads (24%) | SIFT tolerated (0.61); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TOM1L1 | c.488C>A p.A163E | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRIM59 | c.499C>A p.L167M | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TUBB2A | c.792C>G p.H264Q | Missense Mutation (SNP) | VAF 78/648 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- UTP14A | c.459G>T p.Q153H | Missense Mutation (SNP) | VAF 65/348 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- UTP20 | c.6552C>G p.F2184L | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VPS13A | c.1150G>T p.V384L | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF107 | c.830G>A p.C277Y | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AUNIP | c.339T>C p.D113= | Silent (SNP) | VAF 61/379 reads (16%) | called by muse, mutect2, varscan2
- BHLHE22 | c.804G>T p.V268= | Silent (SNP) | VAF 242/569 reads (43%) | catalogued as COSV58861176; called by muse, mutect2, varscan2
- DMXL1 | c.6853T>C p.L2285= | Silent (SNP) | VAF 45/133 reads (34%) | called by muse, mutect2, varscan2
- ESYT2 | c.1914T>C p.S638= (on ENST00000613624; = p.S562= on NM_020728.3) | Silent (SNP) | VAF 171/564 reads (30%) | called by muse, mutect2, varscan2
- FRMPD3 | c.2547C>T p.F849= | Silent (SNP) | VAF 67/336 reads (20%) | called by muse, mutect2, varscan2
- HCFC1 | c.4581G>A p.L1527= | Silent (SNP) | VAF 44/165 reads (27%) | catalogued as COSV60077941; called by muse, mutect2, varscan2
- VDAC1 | c.255T>C p.I85= | Silent (SNP) | VAF 30/238 reads (13%) | called by muse, mutect2, varscan2
- ASPRV1 | chr2:69963387 G>A | 5'Flank (SNP) | VAF 57/290 reads (20%) | catalogued as rs745761241; called by muse, mutect2, varscan2
- ATAD3B | c.*483C>T | 3'UTR (SNP) | VAF 22/134 reads (16%) | catalogued as rs776893650; called by muse, mutect2, varscan2
- C1orf122 | c.*31T>C | 3'UTR (SNP) | VAF 72/358 reads (20%) | catalogued as COSV100888564; called by mutect2, varscan2
- C9orf131 | chr9:35041084 T>C | 5'Flank (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- CAPN12 | c.1687-15T>C | Intron (SNP) | VAF 32/163 reads (20%) | called by muse, mutect2, varscan2
- CEP162 | c.*69G>T | 3'UTR (SNP) | VAF 33/210 reads (16%) | called by muse, mutect2, varscan2
- ESRRG | c.56+15863G>T | Intron (SNP) | VAF 36/256 reads (14%) | called by muse, mutect2, varscan2
- ESRRG | c.56+15862G>C | Intron (SNP) | VAF 37/259 reads (14%) | called by muse, mutect2, varscan2
- LIMA1 | c.1030+21C>T | Intron (SNP) | VAF 52/196 reads (27%) | called by muse, varscan2
- MYBPC3 | c.-34T>A | 5'UTR (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- NRXN1 | c.3719-1385A>G | Intron (SNP) | VAF 53/255 reads (21%) | called by muse, mutect2, varscan2
- PIAS1 | c.24+3132del | Intron (DEL) | VAF 5/30 reads (17%) | called by mutect2, pindel, varscan2
- PIK3C3 | c.-1G>A | 5'UTR (SNP) | VAF 23/87 reads (26%) | catalogued as rs1265241271; called by muse, mutect2, varscan2
- RNF207 | c.324+129G>A | Intron (SNP) | VAF 37/203 reads (18%) | called by muse, mutect2, varscan2
